Surgical pathology report (de-identified scan), TCGA case TCGA-SP-A6QD, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University Health Network, specimen TCGA-SP-A6QD-01A (Primary Tumor).

[page 1 of 2]
LABORATORY MEDICINE PROGRAM

Surgical Pathology Consultation Report

Patient Name:	[REDACTED]	Accession #:	[REDACTED]
MRN:	[REDACTED]	Service:	
DOB:	[REDACTED]	Collected:	
		Received:	
Gender:	[REDACTED]	Location:	
HCN:	[REDACTED]	Facility:	
Ordering MD:		Reported:	
Copy To:			

Specimen(s) Received

1. Right adrenal for tissue banking

Diagnosis

Pheochromocytoma: Adrenal (right) adrenalectomy specimen

Electronically verified by:

Clinical History

Pheochromocytoma of the right adrenal

Gross Description

The specimen container labeled with the patient's name and as "right adrenal" contains an enlarged adrenal gland that weighs 109.5 grams and measures 2.5 x 4.0 x 5.4 cm. The surface is painted with silver nitrate. On section, the tumor measures 2.5 x 2.5 x 3.0 cm. Three pieces of tumor and three pieces of adrenal are stored frozen. Sections are submitted as follows:

1A-H representative transverse sections from one end of the specimen to the other end

Microscopic Description

DOMINANT LESION: adrenal tumor

SIZE: 5.4 cm maximum dimension

WEIGHT: 109.5 g

ARCHITECTURE: solid nesting "zellballen" architecture

CYTOLOGY: polygonal cells with indistinct cell borders, abundant basophilic cytoplasm and focal nuclear pleomorphism

DEGENERATION: vascular congestion and focal stromal hemorrhage

ENCAPSULATION: incomplete capsule

CAPSULAR INVASION: no frank invasion identified

EXTRA-ADRENAL INVASION: not identified

RESECTION MARGINS: not involved

LYMPHOVASCULAR INVOLVEMENT: not identified

OTHER ADRENAL PATHOLOGY: none; no medullary hyperplasia

LYMPH NODES: none identified

[page 2 of 2]
Surgical Pathology Consultation Report

Source: NCI Genomic Data Commons file d9870015-30fa-4253-945a-9f4a6ba10bc4 (TCGA-SP-A6QD.6FB76F33-A70A-49C6-B8E8-46D249CCBB04.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).